Surgical pathology report (de-identified scan), TCGA case TCGA-06-0158, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0158-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

BRAIN, LEFT TEMPORAL LOBE: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: Brain, left temporal lobe. 2) Enhancing tumor.
3) Non-enhancing tumor.

Clinical History and Pre-Op Dx: The patient is a survivor of [REDACTED] He has had a diagnosis of brain tumor for the past several years, but recently it has taken a turn for the worse.

INTRAOPERATIVE CONSULTATION: Glioma with areas of necrosis, by [REDACTED]

GROSS PATHOLOGY: Three fragments of soft grayish-white tissue entirely submitted after the Intraoperative Consultation in three separate cassettes.

MICROSCOPIC: All three fragments show evidence of replacement of the normal brain parenchyma by relatively cellular tumor composed of fibrillary astrocytes. There is considerable nuclear pleomorphism and many vessels show hypertrophy and hyperplasia of the endothelial lining. Occasional atypical mitoses are also visible. The sample submitted in cassette #3 shows several areas of coagulation necrosis and at least one large, recently thrombosed vessel.

Additional sections will be reacted with antiserum against MIB-1 and an addendum will be issued when these become available.

B.
SPECIMEN: Enhancing tumor.
FIXATIVE: None.
GENERAL: Triangular portion of gray-white to purple rubbery tissue 0.9 x 0.5 x 0.2 cm.; trisected.
SECTIONS: X1, all.

C.
SPECIMEN: Non-enhancing tumor.
FIXATIVE: None.
GENERAL: Triangular portion of tan-gray rubbery tissue, 1.7 x 1.0 x 0.9 cm.; trisected.
SECTIONS: X2, all.

MICROSCOPIC: Two histology slides show multiple fragments of a [REDACTED]

[page 2 of 2]
[REDACTED]

neoplasm composed of anaplastic glial cells, a few of which show the features of fibrillary astrocytes. The tumor has high cellularity, frequent individual necrotic cells and prominent hyperplastic blood vessels. Atypical mitotic figures are also encountered.

TCGA-06-0158

The original diagnosis of glioblastoma multiforme remains unchanged.

ADDENDUM: The following dictation has been requested by the attending physician.

Block #1 from the sample labeled "tumor" shows total effacement of the brain tissue by highly cellular well vascularized neoplasm composed of fibrillary astrocytes. There are occasional and very small foci of necrosis.

#2 from the specimen labeled "low grade" a fragment in which the brain tissue parenchyma is completely effaced by a highly cellular neoplasm having microscopic features similar to those described in sample #1. There are numerous prominent small blood vessels with hyperplastic endothelial lining.

#3 from the sample labeled "contrast-enhancing lesion" a sample of neoplastic fibrillary astrocytes that is highly cellular very well vascularized and contains large vessels with recent thrombosis of the lumen. Areas of coagulation necrosis are easily visible. Otherwise, the microscopic features are very similar to those described under 1 and 2.

Additional sections from block #2 were reacted with antiserum against MIB-1. On the average, 5 to 10% of the neoplastic cells immunoreact with MIB-1.

The original diagnosis remains unchanged.

[REDACTED]

Source: NCI Genomic Data Commons file 288f1dd6-74bd-4e64-bb89-17695cfb2505 (TCGA-06-0158.584952B9-BBD0-4DA2-9A40-CD0291E8F780.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).